Somatic mutation profile of tumor specimen ASCProject_0220_T3_WES (aliquot ASCProject_0220_T3_WES_1) from CMI case ASCProject_0220, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 67.1 years (24,491 days).
Specimen ASCProject_0220_T3_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head, Face or Neck, NOS; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68087786-447c-4104-b616-1adce3cd1afb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0220_SALIVA (Saliva), aliquot ASCProject_0220_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a3152bf-330a-4967-89eb-1f98a270a933

The open-access MAF lists 1,499 somatic variants for this specimen: 896 protein-altering or splice-affecting, 422 silent, 181 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 794, Silent 422, Intron 80, Nonsense Mutation 51, RNA 36, 3'UTR 27, Splice Region 23, 5'UTR 16, Splice Site 14, 3'Flank 11, 5'Flank 10, Frame Shift Del 10.

Variants (750 of 1,499; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP2C8 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 31/132 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV64876179; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 29/98 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | hotspot (GDC flag); catalogued as rs1064794618, COSV52751414, COSV53223969, COSV53499187; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.158G>A p.W53* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | hotspot (GDC flag); catalogued as rs876658483, COSV52774899; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USH2A | c.11954G>A p.W3985* | Nonsense Mutation (SNP) | VAF 23/146 reads (16%) | catalogued as rs397517976, COSV56421073; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.2024C>T p.P675L | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.619); catalogued as COSV70031229; called by muse, mutect2, varscan2
- ABCB5 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99328766; called by muse, mutect2, varscan2
- ABCB5 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51714833; called by muse, mutect2, varscan2
- ABCC11 | c.2216C>T p.S739L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs150250426; called by muse, mutect2, varscan2
- ABCC12 | c.3784C>T p.R1262C | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs756690220, COSV60918378; called by muse, mutect2
- ABCC3 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.058); catalogued as rs371378724; called by muse, mutect2, varscan2
- ABCD2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV100429691; called by muse, mutect2, varscan2
- AC100868.1 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV51842958; called by muse, mutect2, varscan2
- ACAN | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.308); catalogued as rs758892087, COSV100717447, COSV100717452; called by muse, mutect2, varscan2
- ACAN | c.2774G>A p.R925K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV61369203; called by muse, mutect2, varscan2
- ACBD3 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs267598392; called by muse, mutect2, varscan2
- ACD | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.013); catalogued as COSV54665920, COSV99538042; called by muse, mutect2, varscan2
- ACOX3 | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs902570784; called by muse, mutect2, varscan2
- ACTN2 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs145450474, COSV63977118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM11 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV52349480; called by muse, mutect2, varscan2
- ADAMTS2 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV52380916; called by muse, mutect2, varscan2
- ADGB | c.2114C>T p.P705L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as rs868014514; called by muse, mutect2, varscan2
- ADGRG4 | c.6095C>T p.S2032F | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs145052934, COSV54951114, COSV54964574; called by muse, mutect2, varscan2
- AGBL1 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs371923647, COSV66871729; called by muse, mutect2, varscan2
- AGTR1 | c.-47-1G>A | Splice Site (SNP) | VAF 25/93 reads (27%) | catalogued as COSV62557733; called by muse, mutect2, varscan2
- AL645922.1 | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV54959013; called by muse, mutect2, varscan2
- AMFR | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV51921369; called by mutect2, varscan2
- ANK2 | c.10804C>T p.R3602* | Nonsense Mutation (SNP) | VAF 39/153 reads (25%) | catalogued as COSV52152721; called by muse, mutect2, varscan2
- ANKRD30A | c.1522G>A p.E508K (on ENST00000611781; = p.E452K on NM_052997.2) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as rs1431263629, COSV100654602; called by muse, varscan2
- ANKRD33B | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1226802406; called by muse, mutect2, varscan2
- ANKRD35 | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.99); catalogued as COSV62911831; called by muse, mutect2, varscan2
- ANOS1 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); catalogued as rs200390149, COSV52928844; called by muse, varscan2
- AOX1 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs753517873; called by muse, mutect2, varscan2
- AOX1 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV65979784; called by muse, mutect2, varscan2
- ARHGAP15 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV54493223; called by muse, mutect2, varscan2
- ARHGAP20 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs1383408605, COSV52807149; called by muse, mutect2, varscan2
- ARHGEF40 | c.3358C>T p.R1120W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777686185, COSV100069989; called by muse, mutect2, varscan2
- ARMC3 | c.1828G>A p.V610I | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs375931697, COSV99959092; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs754272411; called by muse, mutect2, varscan2
- ARNT2 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV100309580; called by muse, mutect2, varscan2
- ASIC5 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV72232517, COSV72232612; called by muse, mutect2, varscan2
- ASTN1 | c.3166G>A p.D1056N | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV62494018; called by muse, mutect2, varscan2
- ASTN2 | c.1724G>A p.G575E (on ENST00000313400 / NM_001365069.1; = p.G524E on NM_014010.5) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57800281; called by muse, mutect2, varscan2
- ATR | c.5500C>T p.L1834F | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63389971; called by muse, mutect2, varscan2
- ATRX | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 29/60 reads (48%) | catalogued as rs1057523785, COSV64871339; called by muse, mutect2, varscan2
- B4GALT6 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs779821972; called by muse, mutect2, varscan2
- BNC1 | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1466774009; called by muse, mutect2, varscan2
- BRPF3 | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV60209029; called by muse, mutect2, varscan2
- C1QTNF9B | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV101158655; called by muse, mutect2, varscan2
- C1QTNF9B | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs767104648; called by mutect2, varscan2
- C2orf78 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.208); catalogued as rs1181729164; called by muse, mutect2, varscan2
- C3orf18 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs577414859, COSV51750127; called by muse, mutect2, varscan2
- C6orf15 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs753499995; called by muse, mutect2, varscan2
- CACNA1I | c.2846C>T p.S949F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV60817784; called by muse, mutect2
- CACNA1S | c.5275C>T p.P1759S | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs772350429; called by muse, mutect2, varscan2
- CACNB2 | c.605G>A p.G202E (on ENST00000324631 / NM_201596.3; = p.G147E on NM_000724.4) | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV56634126; called by muse, mutect2, varscan2
- CAPN13 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV99700501; called by muse, mutect2, varscan2
- CAPN8 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as rs1333594036; called by muse, mutect2, varscan2
- CCDC27 | c.1139G>A p.R380K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV53901160; called by muse, varscan2
- CCDC27 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV53901773; called by muse, varscan2
- CCDC74A | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.301); catalogued as rs145934024, COSV54605168; called by muse, mutect2, varscan2
- CCNB3 | c.3964C>T p.P1322S | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs868978383, COSV52073984; called by muse, mutect2, varscan2
- CD1C | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs868151001, COSV63805700; called by muse, mutect2, varscan2
- CD1C | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV63807270; called by muse, mutect2, varscan2
- CD300LG | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs780288721, COSV53226146; called by muse, mutect2, varscan2
- CDH23 | c.9904G>A p.E3302K | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs368743687, CM140438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH6 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as rs150163280; called by muse, mutect2, varscan2
- CELSR3 | c.3010G>A p.E1004K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs754362154; called by muse, mutect2, varscan2
- CETN2 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV64743498; called by muse, mutect2, varscan2
- CFAP251 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99995850; called by muse, mutect2, varscan2
- CFAP47 | c.1613C>T p.S538L | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767801607, COSV99935514; called by muse, mutect2, varscan2
- CFAP54 | c.3040C>T p.L1014F | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1448231498; called by muse, mutect2, varscan2
- CFAP61 | c.3088C>T p.R1030W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs1285111032, COSV99844980; called by muse, mutect2
- CHGB | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 71/98 reads (72%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as COSV66761381; called by muse, varscan2
- CHSY1 | c.1505G>A p.G502E | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV54253430; called by muse, mutect2
- CLCNKB | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.838); catalogued as COSV65160449; called by muse, mutect2, varscan2
- CLEC12B | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752650812; called by muse, mutect2, varscan2
- CLIC5 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs1488754576; called by muse, mutect2, varscan2
- CMYA5 | c.3431C>T p.S1144L | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV71409946; called by muse, mutect2, varscan2
- CNTN3 | c.2484G>A p.W828* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV55163979; called by muse, varscan2
- CNTN3 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as COSV55165405; called by muse, mutect2, varscan2
- CNTN4 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1445392566; called by muse, mutect2, varscan2
- CNTN5 | c.2723G>A p.G908E | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54282866; called by muse, mutect2, varscan2
- COL14A1 | c.5111C>T p.P1704L | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99035024; called by muse, mutect2, varscan2
- COL19A1 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59578306; called by muse, varscan2
- COL19A1 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.978); catalogued as COSV100505520; called by muse, varscan2
- COL22A1 | c.2700G>A p.P900= | Splice Region (SNP) | VAF 30/112 reads (27%) | catalogued as rs1029399664, COSV100278875; called by muse, mutect2, varscan2
- COL27A1 | c.80G>A p.W27* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as rs1271293702; called by muse, mutect2, varscan2
- COL2A1 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as COSV61528952; called by muse, mutect2, varscan2
- COL4A1 | c.1832C>G p.A611G | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as COSV101011204; called by muse, mutect2, varscan2
- COL6A5 | c.6499C>T p.Q2167* (on ENST00000312481; = p.Q2163* on NM_153264.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 58/126 reads (46%) | catalogued as COSV55214461; called by muse, mutect2, varscan2
- COL9A1 | c.2153G>A p.G718E | Missense Mutation (SNP) | VAF 132/309 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868065305, COSV57888861; called by muse, mutect2, varscan2
- CPVL | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 85/156 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55305561; called by muse, mutect2, varscan2
- CPVL | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 86/157 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775870649, COSV55301375; called by muse, mutect2, varscan2
- CRACD | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1213933016; called by muse, mutect2
- CREB3L1 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV55830552; called by muse, mutect2, varscan2
- CSMD2 | c.6994G>A p.E2332K | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.403); catalogued as COSV53933880; called by muse, mutect2, varscan2
- CSMD2 | c.2989C>T p.R997W | Missense Mutation (SNP) | VAF 79/246 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs752575603, COSV53933679; called by muse, mutect2, varscan2
- CSMD3 | c.3542C>T p.P1181L (on ENST00000297405 / NM_001363185.1; = p.P1077L on NM_052900.3) | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1237224160, COSV52243593; called by muse, mutect2, varscan2
- CSPG4 | c.4507G>A p.D1503N | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371941921; called by muse, mutect2, varscan2
- CTTNBP2 | c.2140C>T p.L714F | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756636212; called by muse, mutect2, varscan2
- CUL4B | c.1311G>A p.Q437= | Splice Region (SNP) | VAF 17/126 reads (13%) | catalogued as rs1373958825, COSV100340583; called by muse, mutect2, varscan2
- CYP4F2 | c.648G>A p.E216= | Splice Region (SNP) | VAF 9/23 reads (39%) | catalogued as COSV50000519; called by muse, mutect2, varscan2
- DAG1 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs144795781, COSV100445113; called by muse, mutect2, varscan2
- DCAF10 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV54292549; called by muse, mutect2, varscan2
- DCAF12L2 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1456872543, COSV63582594; called by muse, varscan2
- DCAF12L2 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.769); catalogued as COSV63583673; called by muse, varscan2
- DCC | c.4009C>T p.R1337* | Nonsense Mutation (SNP) | VAF 141/368 reads (38%) | catalogued as rs773315729, COSV71427767; called by muse, mutect2, varscan2
- DCLK2 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761382874, COSV56208515; called by muse, mutect2, varscan2
- DENND2A | c.1337C>T p.T446I | Missense Mutation (SNP) | VAF 69/126 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99325693; called by muse, mutect2, varscan2
- DEPDC1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100920273; called by muse, mutect2, varscan2
- DGKB | c.908G>A p.R303K | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1196598454; called by muse, mutect2, varscan2
- DIP2C | c.2350G>A p.G784R | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs1037243274, COSV99793927; called by muse, mutect2, varscan2
- DMD | c.4510C>T p.H1504Y | Missense Mutation (SNP) | VAF 98/421 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as rs1469008607; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMGDH | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs890490693; called by muse, mutect2, varscan2
- DMP1 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as rs1337612531; called by muse, mutect2, varscan2
- DNAH1 | c.2089G>A p.V697M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.373); catalogued as rs757769710, COSV101327423; called by muse, mutect2, varscan2
- DNAH10 | c.973G>A p.E325K (on ENST00000409039; = p.E264K on NM_207437.3) | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV68995707; called by muse, mutect2, varscan2
- DNAH3 | c.8714G>A p.R2905Q | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs753758237; called by muse, mutect2, varscan2
- DNAH7 | c.4625C>T p.S1542F | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs749539806, COSV56752041; called by muse, varscan2
- DNAH7 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56752353; called by mutect2, varscan2
- DNER | c.1979G>A p.G660E | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1559332064; called by muse, mutect2, varscan2
- DSEL | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745800552; called by muse, mutect2, varscan2
- DSPP | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.088); catalogued as rs759676218; called by muse, mutect2, varscan2
- DYSF | c.1741C>T p.L581F | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99250269; called by muse, mutect2, varscan2
- DZIP1 | c.2503C>T p.P835S (on ENST00000347108; = p.P816S on NM_014934.5) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.154); catalogued as rs761397930; called by muse, mutect2, varscan2
- EBAG9 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1021848254; called by muse, varscan2
- EGF | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs778787208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGFLAM | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.248); catalogued as rs1298617781; called by muse, mutect2, varscan2
- ENAH | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52865876; called by muse, mutect2, varscan2
- EPHA6 | c.2755G>A p.D919N (on ENST00000389672 / NM_001080448.3; = p.D311N on NM_173655.4) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs758493908, COSV67585469, COSV67590499; called by muse, mutect2, varscan2
- EPPIN-WFDC6 | c.454A>T p.R152* | Nonsense Mutation (SNP) | VAF 18/168 reads (11%) | catalogued as rs1223892673; called by muse, mutect2, varscan2
- ERBB4 | c.2608G>A p.G870R | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.783); catalogued as COSV61470774; called by muse, mutect2, varscan2
- ERICH3 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.346); catalogued as rs1422321327; called by muse, mutect2, varscan2
- ERICH5 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV59314997; called by muse, mutect2
- ETV3 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1432305060; called by muse, mutect2, varscan2
- EYS | c.3161G>A p.G1054E | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as COSV65482352; called by muse, mutect2, varscan2
- FAM120C | c.2491G>A p.A831T | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782071052; called by muse, mutect2, varscan2
- FAM131B | c.-56G>A | Splice Region (SNP) | VAF 34/104 reads (33%) | catalogued as rs1445716572, COSV101281761; called by muse, mutect2, varscan2
- FAM78B | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867702228; called by muse, mutect2, varscan2
- FAM83B | c.2029C>T p.P677S | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV60924112; called by muse, mutect2, varscan2
- FBN2 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV52503487; called by muse, mutect2, varscan2
- FBRSL1 | c.2413C>T p.R805W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1334174477; called by mutect2, varscan2
- FBXO38 | c.2711C>T p.S904F (on ENST00000340253 / NM_205836.3; = p.S829F on NM_030793.5) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57029095; called by muse, varscan2
- FBXO41 | c.1880G>A p.R627Q | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs180788657; called by muse, mutect2, varscan2
- FCRL4 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54864083; called by muse, mutect2, varscan2
- FERD3L | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1164213501; called by muse, mutect2, varscan2
- FERD3L | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.1); catalogued as rs1408119557; called by muse, mutect2, varscan2
- FGF12 | c.445G>A p.E149K (on ENST00000454309 / NM_021032.5; = p.E87K on NM_004113.6) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53167371; called by muse, mutect2, varscan2
- FGG | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM138482; called by muse, mutect2, varscan2
- FLG | c.5422G>A p.E1808K | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.931); catalogued as rs750597343, COSV64237965, COSV64245424; called by muse, mutect2, varscan2
- FLG | c.2900C>T p.S967F | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100911457; called by muse, mutect2, varscan2
- FLG2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV101165662; called by muse, mutect2, varscan2
- FLT3 | c.1850G>A p.G617E | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54049176, COSV54063534; called by muse, mutect2, varscan2
- FMNL1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs367724765, COSV100056248; called by muse, mutect2, varscan2
- FOXN4 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs1401302883, COSV54492459; called by muse, mutect2, varscan2
- FREM2 | c.1981C>T p.H661Y | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as rs1177378226; called by muse, mutect2, varscan2
- FRMD7 | c.1584G>A p.M528I | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100048848; called by muse, mutect2, varscan2
- FSHR | c.153G>A p.L51= | Splice Region (SNP) | VAF 28/122 reads (23%) | catalogued as COSV58620432, COSV58625002; called by muse, mutect2, varscan2
- GABRB3 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs990827657; called by muse, mutect2, varscan2
- GCK | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs762419802, CM081273; called by muse, mutect2, varscan2
- GFI1B | c.667C>A p.R223S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV100253925; called by muse, mutect2, varscan2
- GGA1 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.449); catalogued as COSV57331861; called by muse, mutect2, varscan2
- GHR | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 65/190 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs768212765; called by muse, mutect2, varscan2
- GJB3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64904888; called by muse, mutect2, varscan2
- GJD2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51748623, COSV51749089; called by muse, mutect2, varscan2
- GK | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV66736177; called by muse, mutect2
- GLI1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs775119859; called by muse, mutect2, varscan2
- GOT1L1 | c.538G>T p.V180F | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as COSV56874980; called by muse, mutect2, varscan2
- GPR179 | c.1933G>A p.D645N (on ENST00000621958; = p.D644N on NM_001004334.4) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.777); catalogued as rs752900382; called by muse, mutect2, varscan2
- GRIA4 | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV56882122; called by muse, mutect2, varscan2
- GRIK5 | c.1640G>A p.W547* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV53477999; called by muse, mutect2, varscan2
- GRIN3A | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as rs866020232; called by muse, mutect2, varscan2
- GRK5 | c.764C>T p.T255I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745516627; called by muse, mutect2, varscan2
- GRM4 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757177526, COSV65219126; called by muse, mutect2, varscan2
- GRWD1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs140220072; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56091363; called by muse, mutect2
- HAO1 | c.956G>A p.W319* | Nonsense Mutation (SNP) | VAF 61/124 reads (49%) | catalogued as COSV101113153; called by muse, mutect2, varscan2
- HCN3 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.334); catalogued as COSV61362182; called by muse, mutect2, varscan2
- HDAC9 | c.2225G>A p.W742* | Nonsense Mutation (SNP) | VAF 94/192 reads (49%) | catalogued as COSV101286866; called by muse, mutect2, varscan2
- HDGFL1 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1371772218; called by muse, mutect2, varscan2
- HECW1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 73/136 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV67840443; called by muse, mutect2, varscan2
- HFM1 | c.3890G>A p.G1297E | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.781); catalogued as rs1448831022; called by muse, mutect2, varscan2
- HIF1AN | c.926C>G p.P309R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54500795; called by muse, varscan2
- HNRNPL | c.1560C>T p.I520= | Splice Region (SNP) | VAF 17/78 reads (22%) | catalogued as rs1337283642, COSV99670470; called by muse, mutect2, varscan2
- HNRNPUL1 | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as rs767128887; called by muse, mutect2
- HOOK2 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as rs750079184, COSV53402836; called by muse, mutect2, varscan2
- HOXC5 | c.167A>G p.N56S | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.157); catalogued as rs1460220361; called by muse, mutect2, varscan2
- HRNR | c.1313G>A p.S438N | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV64256667; called by muse, mutect2, varscan2
- HS3ST3A1 | c.639G>A p.M213I | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.146); catalogued as rs1280811570, COSV52372779; called by muse, mutect2, varscan2
- HSF5 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 79/112 reads (71%) | SIFT tolerated (0.35); PolyPhen benign (0.169); catalogued as rs181008689; called by muse, mutect2, varscan2
- HTR1D | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs749764511, COSV58447366; called by muse, mutect2, varscan2
- HTR1D | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.063); catalogued as rs771429701; called by muse, mutect2, varscan2
- HTR2A | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.042); catalogued as rs763899284, COSV66326523; called by muse, mutect2, varscan2
- IFT52 | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100887683; called by muse, mutect2, varscan2
- IGHV3-53 | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.091); catalogued as rs1301279350; called by muse, mutect2, varscan2
- IGSF21 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52144668; called by muse, mutect2, varscan2
- IL13RA1 | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs775001455, COSV65424217, COSV65424292; called by muse, mutect2, varscan2
- IL18RAP | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as rs1467644509; called by muse, varscan2
- IL36B | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52084330; called by muse, mutect2, varscan2
- INAVA | c.1411G>A p.G471S | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs745556773; called by muse, mutect2, varscan2
- INPP4B | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV53740510; called by muse, mutect2, varscan2
- INSYN2A | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.325); catalogued as rs745852102; called by muse, mutect2, varscan2
- IQGAP3 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369044095; called by muse, mutect2, varscan2
- ITIH2 | c.2258G>A p.G753E | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV64432199; called by muse, mutect2, varscan2
- IWS1 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.115); catalogued as rs867898584, COSV54869696; called by muse, mutect2, varscan2
- JAKMIP1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748860696; called by muse, mutect2, varscan2
- KCNA5 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52903923, COSV99364183; called by muse, mutect2, varscan2
- KCNF1 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV54462112; called by muse, mutect2, varscan2
- KCNH8 | c.1517G>A p.R506K | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV60476932; called by muse, mutect2, varscan2
- KCNK10 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs777722776; called by mutect2, varscan2
- KCNT2 | c.3211G>A p.D1071N | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs1402621988; called by muse, mutect2
- KCNU1 | c.1629C>T p.A543= | Splice Region (SNP) | VAF 30/54 reads (56%) | catalogued as COSV67759425; called by muse, mutect2, varscan2
- KCTD8 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1248366683, COSV63587201; called by muse, mutect2, varscan2
- KDM6B | c.3217A>G p.K1073E | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.549); catalogued as rs779117553; called by muse, mutect2, varscan2
- KIAA0586 | c.964C>T p.P322S (on ENST00000619416 / NM_001244190.2; = p.P337S on NM_014749.5) | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV99707243; called by muse, mutect2, varscan2
- KIAA0586 | c.965C>T p.P322L (on ENST00000619416 / NM_001244190.2; = p.P337L on NM_014749.5) | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV54179395; called by muse, mutect2, varscan2
- KIAA2012 | c.2735C>T p.S912L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.27); catalogued as rs1274317115; called by muse, mutect2
- KIF17 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV56122388; called by muse, mutect2, varscan2
- KRT1 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 53/169 reads (31%) | catalogued as rs759244867; called by muse, mutect2, varscan2
- KRTAP10-10 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs148816939; called by muse, mutect2, varscan2
- KRTAP10-5 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs782773002, COSV100552744; called by muse, varscan2
- KRTAP13-2 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.272); catalogued as COSV67762311; called by muse, mutect2, varscan2
- LAMA2 | c.7159G>A p.D2387N | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101370256; called by muse, mutect2, varscan2
- LAMA2 | c.7690C>T p.L2564F | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV70350282, COSV70351115, COSV70351952; called by muse, mutect2, varscan2
- LRFN5 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV53243984; called by muse, mutect2, varscan2
- LRIT1 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1308637635, COSV64512911; called by mutect2, varscan2
- LRP2 | c.2752G>A p.G918R | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55546970; called by muse, mutect2, varscan2
- LRRK2 | c.4750C>T p.H1584Y | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV100109853; called by muse, mutect2, varscan2
- MAD1L1 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs1044593522; called by muse, mutect2
- MADD | c.1185G>A p.W395* | Nonsense Mutation (SNP) | VAF 26/122 reads (21%) | catalogued as COSV60629773; called by muse, varscan2
- MAGEL2 | c.2878G>A p.G960R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as rs1253511015; called by muse, mutect2, varscan2
- MAP3K14 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs1266969497; called by muse, mutect2, varscan2
- MAP7D2 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1478709456; called by muse, mutect2, varscan2
- MARVELD3 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51705210; called by muse, mutect2, varscan2
- MARVELD3 | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772060113; called by muse, mutect2, varscan2
- MBTPS2 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.972); catalogued as COSV101068443; called by muse, mutect2, varscan2
- MECOM | c.2585G>A p.R862K (on ENST00000468789 / NM_001105078.4; = p.R1050K on NM_004991.4) | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as COSV52960378, COSV52967265; called by muse, mutect2, varscan2
- MEGF6 | c.2779C>T p.H927Y | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1247667099; called by muse, mutect2, varscan2
- MGRN1 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.498); catalogued as rs985103801; called by muse, mutect2, varscan2
- MID1 | c.864+1G>A p.X288_splice | Splice Site (SNP) | VAF 36/130 reads (28%) | catalogued as CS071241; called by muse, mutect2, varscan2
- MLH3 | c.2906C>T p.P969L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs776422424; called by muse, mutect2, varscan2
- MMD | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 69/102 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50434708; called by muse, mutect2, varscan2
- MROH8 | c.861C>T p.C287= | Splice Region (SNP) | VAF 16/62 reads (26%) | catalogued as rs775006044, COSV54126847; called by muse, mutect2, varscan2
- MS4A1 | c.833A>G p.N278S | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs1217693252; called by muse, mutect2, varscan2
- MTA3 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs759672314; called by muse, mutect2
- MTUS2 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV70916396; called by muse, mutect2, varscan2
- MUC12 | c.3448C>T p.P1150S (on ENST00000379442; = p.P1007S on NM_001164462.1) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs1287921618; called by mutect2, varscan2
- MUC12 | c.3449C>T p.P1150L (on ENST00000379442; = p.P1007L on NM_001164462.1) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs548880460; called by mutect2, varscan2
- MUC16 | c.23866G>A p.D7956N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs372572295; called by muse, mutect2, varscan2
- MUC16 | c.7208C>T p.S2403F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs1357636577, COSV67447684; called by muse, mutect2, varscan2
- MXRA5 | c.4327C>T p.L1443F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0.108); catalogued as COSV54250666; called by muse, mutect2, varscan2
- MYBPHL | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1442900581; called by muse, mutect2, varscan2
- MYF6 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57351394; called by muse, mutect2, varscan2
- MYH1 | c.3616G>A p.E1206K | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs375020058; called by muse, mutect2, varscan2
- MYH15 | c.5149G>A p.E1717K | Missense Mutation (SNP) | VAF 99/247 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56313966; called by muse, mutect2, varscan2
- MYH7 | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 35/97 reads (36%) | catalogued as rs730880852, CM144973, COSV62517904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO18B | c.3868G>A p.G1290R | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV59129637; called by muse, mutect2, varscan2
- MYO5A | c.2620C>T p.R874W | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1418196344, COSV62560848; called by muse, mutect2, varscan2
- MYOCD | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 102/313 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1490304871; called by muse, varscan2
- N4BP2 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); catalogued as COSV54707256; called by muse, mutect2, varscan2
- NACAD | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs752627670; called by muse, mutect2, varscan2
- NCKAP5 | c.5425C>T p.P1809S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs758147721, COSV58452161; called by mutect2, varscan2
- NDUFV1 | c.73-6C>T | Splice Region (SNP) | VAF 37/201 reads (18%) | catalogued as rs768190593; called by muse, mutect2, varscan2
- NIN | c.5350C>T p.R1784W (on ENST00000382041 / NM_182946.1; = p.R1071W on NM_016350.4) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs142213280, COSV99812486; called by muse, mutect2, varscan2
- NLRP13 | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as rs200519393, COSV61624417; called by muse, mutect2, varscan2
- NLRP13 | c.2383G>A p.G795R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV100738231; called by muse, mutect2, varscan2
- NMU | c.220-1G>A p.X74_splice | Splice Site (SNP) | VAF 19/134 reads (14%) | catalogued as rs759226013; called by muse, mutect2, varscan2
- NOBOX | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as rs761911047; called by muse, mutect2, varscan2
- NPHP3 | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as rs1210667662; called by muse, mutect2, varscan2
- NPHP3 | c.1973C>T p.P658L | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.86); catalogued as rs980423777; called by muse, mutect2, varscan2
- NRSN1 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs753743189; called by muse, mutect2, varscan2
- NWD2 | c.3727G>A p.G1243R | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs749591892, COSV58753163; called by muse, mutect2, varscan2
- OPRD1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV52384031; called by muse, mutect2, varscan2
- OR10H5 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755916276; called by muse, mutect2, varscan2
- OR1A2 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101126390; called by muse, mutect2, varscan2
- OR1D2 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV58922549; called by muse, mutect2, varscan2
- OR2AP1 | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.714); catalogued as rs1280213376; called by muse, mutect2, varscan2
- OR2J3 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV65849836; called by muse, mutect2, varscan2
- OR4C13 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs563481475; called by muse, mutect2, varscan2
- OR4C15 | c.707C>T p.P236L (on ENST00000314644; = p.P182L on NM_001001920.2) | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs375979136, COSV58950833; called by muse, mutect2, varscan2
- OR4P4 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs774695651, COSV58921030; called by muse, mutect2, varscan2
- OR51S1 | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV59059819; called by muse, mutect2, varscan2
- OR56A5 | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.17); catalogued as rs1488284529, COSV60826792; called by muse, mutect2, varscan2
- OR5H14 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs768046296, COSV71193536; called by muse, mutect2, varscan2
- OR5J2 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100399121, COSV56620492; called by muse, mutect2, varscan2
- OR5L2 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1182898489; called by muse, mutect2, varscan2
- OR5V1 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs867076795, COSV65826389; called by muse, mutect2, varscan2
- OR8K3 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs980476666, COSV57130846, COSV57133357; called by muse, varscan2
- OR8U1 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100164153, COSV56414361; called by muse, mutect2, varscan2
- OTUD7B | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV64917600; called by muse, mutect2
- P2RX1 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV56653815; called by muse, mutect2, varscan2
- PADI2 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226075265; called by muse, varscan2
- PAPSS2 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs749210631; called by muse, mutect2, varscan2
- PAQR6 | c.179+8G>A | Splice Region (SNP) | VAF 37/134 reads (28%) | catalogued as rs773087107, COSV52746764; called by muse, mutect2, varscan2
- PCDH15 | c.5656G>T p.V1886F | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.254); catalogued as COSV57298113; called by muse, mutect2, varscan2
- PCDH15 | c.5317C>T p.P1773S | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs1332993779, COSV100226171; called by muse, mutect2, varscan2
- PCDHA2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.911); catalogued as COSV65367219; called by muse, mutect2, varscan2
- PCDHB4 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as rs140862802, COSV52022703; called by mutect2, varscan2
- PCDHB6 | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50698122; called by muse, mutect2, varscan2
- PCDHGA11 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs779718690, COSV53963851; called by muse, mutect2, varscan2
- PCDHGB2 | c.2315C>T p.P772L | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs766571642, COSV53927749; called by muse, mutect2, varscan2
- PCLAF | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100257050; called by muse, mutect2, varscan2
- PCSK5 | c.2515G>A p.D839N | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as COSV65083278; called by muse, mutect2, varscan2
- PDHA2 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.619); catalogued as rs865933539, COSV54779463; called by muse, mutect2, varscan2
- PDP1 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 84/169 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52600374; called by muse, mutect2, varscan2
- PHACTR3 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63031071; called by muse, mutect2
- PHF2 | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as rs761049923; called by muse, mutect2, varscan2
- PHGDH | c.357-8C>T | Splice Region (SNP) | VAF 45/249 reads (18%) | catalogued as rs762922421; called by muse, mutect2, varscan2
- PHGDH | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV101025110, COSV65570344; called by muse, mutect2, varscan2
- PHRF1 | c.1718C>T p.P573L (on ENST00000264555 / NM_001286581.2; = p.P572L on NM_020901.4) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs751366941; called by muse, varscan2
- PIK3R2 | c.1144C>T p.H382Y | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV55847741; called by muse, mutect2, varscan2
- PLA2G4A | c.1718C>T p.S573F | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs867238308, COSV66557656; called by muse, mutect2, varscan2
- PLCB2 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778331998; called by muse, mutect2, varscan2
- PLD5 | c.1141C>T p.L381F (on ENST00000442594; = p.L319F on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100139887; called by muse, mutect2, varscan2
- PNPLA6 | c.1160C>T p.P387L (on ENST00000414982 / NM_001166111.2; = p.P339L on NM_006702.5) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1362018954, COSV99654484; called by muse, mutect2, varscan2
- PORCN | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 92/215 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as rs782086023, COSV58225566; called by muse, mutect2, varscan2
- POU6F2 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.647); catalogued as rs1240922902; called by muse, mutect2, varscan2
- PPFIA2 | c.2666G>A p.R889Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.944); catalogued as rs1414348237, COSV61040047; called by muse, mutect2, varscan2
- PPFIA2 | c.88C>T p.H30Y | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV61043853; called by muse, mutect2, varscan2
- PPP1R42 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV100221023, COSV61207368; called by muse, mutect2, varscan2
- PPP2R2B | c.556G>A p.E186K (on ENST00000394409; = p.E252K on NM_181674.2) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV60765231; called by muse, mutect2, varscan2
- PRDM9 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV57008350; called by muse, mutect2, varscan2
- PRPSAP2 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as rs747098801; called by muse, mutect2, varscan2
- PRSS21 | c.812A>G p.Y271C | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567276530; called by muse, mutect2, varscan2
- PRX | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV52533389; called by muse, mutect2, varscan2
- PTCHD1 | c.2326G>T p.V776F | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV65061759; called by muse, mutect2, varscan2
- PTP4A2 | c.187C>T p.L63= | Splice Region (SNP) | VAF 35/90 reads (39%) | catalogued as COSV59775160; called by muse, mutect2, varscan2
- PTPRC | c.1669C>T p.H557Y | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1553241686; called by muse, mutect2, varscan2
- PTPRD | c.3002G>A p.G1001E | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV61950514; called by muse, mutect2, varscan2
- PTPRO | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs373962189; called by muse, mutect2, varscan2
- PTPRT | c.3643G>A p.D1215N | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100626005; called by muse, mutect2, varscan2
- RAET1G | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1271176037; called by muse, mutect2, varscan2
- RBAK | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 119/154 reads (77%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs1278822387; called by muse, mutect2, varscan2
- RBM25 | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV99998604; called by muse, mutect2, varscan2
- RBM25 | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56199119; called by muse, mutect2, varscan2
- RFX6 | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); catalogued as rs769010999; called by muse, mutect2, varscan2
- RFX6 | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs748473939, COSV99072646; called by muse, mutect2, varscan2
- RGL1 | c.1802C>T p.S601F (on ENST00000360851 / NM_001297672.2; = p.S636F on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV58980409; called by muse, mutect2, varscan2
- RP1 | c.2866G>A p.D956N | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55110909, COSV55126262; called by muse, mutect2, varscan2
- RPGRIP1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV52848725; called by muse, mutect2, varscan2
- RPP30 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs748899504; called by muse, mutect2, varscan2
- RPTOR | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 49/76 reads (64%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV60818239; called by muse, mutect2, varscan2
- RRP36 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | catalogued as rs371077361; called by muse, mutect2
- RYR1 | c.5486C>T p.P1829L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV100616251; called by muse, mutect2, varscan2
- RYR1 | c.6273C>T p.P2091= | Splice Region (SNP) | VAF 15/50 reads (30%) | catalogued as rs1295561951, COSV62112481; called by muse, mutect2, varscan2
- RYR2 | c.3608C>T p.P1203L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV63663418; called by muse, mutect2, varscan2
- SAA2 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765674488, COSV56777025; called by muse, mutect2, varscan2
- SALL1 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51762761; called by muse, mutect2, varscan2
- SCN10A | c.2450G>A p.R817Q | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs201068959, COSV71860875; called by muse, mutect2, varscan2
- SCN10A | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.564); catalogued as COSV71862300; called by muse, mutect2, varscan2
- SCN7A | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV101313246; called by muse, mutect2, varscan2
- SCUBE2 | c.2887C>T p.R963* (on ENST00000649792 / NM_001367977.2; = p.R906* on NM_020974.3) | Nonsense Mutation (SNP) | VAF 42/90 reads (47%) | catalogued as rs370986866, COSV58543084; called by muse, mutect2, varscan2
- SCUBE2 | c.850+1G>A p.X284_splice | Splice Site (SNP) | VAF 33/72 reads (46%) | catalogued as rs1033411633; called by muse, mutect2, varscan2
- SCUBE2 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs765518678; called by muse, mutect2, varscan2
- SEC31B | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs776773114; called by muse, mutect2, varscan2
- SEMG1 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as rs1316231549, COSV99725028; called by muse, mutect2
- SERPINA7 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59664893; called by muse, mutect2, varscan2
- SERPINB3 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 103/188 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as rs1436561643; called by muse, mutect2, varscan2
- SERPINC1 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as rs1202691195, COSV62929404; called by muse, mutect2, varscan2
- SGIP1 | c.1749C>G p.I583M | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs375102916; called by muse, mutect2, varscan2
- SH3RF2 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV63038827; called by muse, mutect2, varscan2
- SI | c.2084T>C p.L695S | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52271493; called by muse, mutect2, varscan2
- SLC17A4 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757729766, COSV64957509; called by muse, mutect2, varscan2
- SLC23A3 | c.793C>T p.L265F (on ENST00000409878 / NM_001144889.2; = p.S254= on NM_144712.5) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.94); PolyPhen benign (0.028); catalogued as rs763308844; called by muse, mutect2, varscan2
- SLC34A3 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.017); catalogued as rs1190433400; called by muse, mutect2
- SLC3A1 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV99577713; called by muse, mutect2, varscan2
- SLC45A1 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1355482715, COSV57093552; called by muse, varscan2
- SLC4A4 | c.1766C>T p.S589F (on ENST00000264485 / NM_001098484.3; = p.S545F on NM_003759.4) | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52613484; called by muse, mutect2, varscan2
- SLCO5A1 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52653534; called by muse, mutect2, varscan2
- SMOX | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.812); catalogued as rs768785503, COSV53864339; called by muse, mutect2, varscan2
- SORCS1 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV53895252; called by muse, mutect2, varscan2
- SOS2 | c.3568C>T p.P1190S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.101); catalogued as rs1385319218; called by muse, mutect2
- SPOCD1 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs750295044; called by muse, mutect2, varscan2
- SPRR1B | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.191); catalogued as rs1346256131; called by muse, mutect2, varscan2
- SPTA1 | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 61/347 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267598102, COSV100934909, COSV63755764; called by muse, mutect2, varscan2
- SPTA1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 42/241 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.474); catalogued as COSV63753038; called by muse, mutect2, varscan2
- SSBP2 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as rs139624975; called by muse, mutect2, varscan2
- ST18 | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99389029; called by muse, mutect2, varscan2
- ST8SIA6 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV101112130; called by muse, mutect2, varscan2
- STAC | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs768851881; called by muse, mutect2, varscan2
- STARD13 | c.1580C>T p.P527L (on ENST00000336934 / NM_001243476.3; = p.P409L on NM_052851.3) | Missense Mutation (SNP) | VAF 60/101 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs533317708; called by muse, mutect2, varscan2
- STYK1 | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768420578, COSV50013796, COSV50016028; called by muse, mutect2, varscan2
- SYNE1 | c.23979-8C>T | Splice Region (SNP) | VAF 33/103 reads (32%) | catalogued as rs369328982; called by muse, mutect2, varscan2
- SYT10 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.04); catalogued as COSV99951559; called by muse, mutect2, varscan2
- SYT17 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.885); catalogued as rs200101214, COSV62544901; called by muse, mutect2, varscan2
- SYT3 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as rs1484289495, COSV58899308; called by muse, mutect2, varscan2
- TAAR2 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV51578973; called by muse, mutect2
- TAP2 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 102/314 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145822869; called by muse, mutect2, varscan2
- TAT | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs773076331; called by muse, mutect2, varscan2
- TBCCD1 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751169166; called by muse, mutect2, varscan2
- TBL2 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59786083; called by muse, mutect2, varscan2
- TCFL5 | c.1442C>T p.S481F | Missense Mutation (SNP) | VAF 100/241 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs201348130; called by muse, mutect2, varscan2
- TCHHL1 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as rs1306296995, COSV64286929; called by muse, mutect2, varscan2
- TDRD9 | c.3998G>A p.R1333K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs766061213, COSV59153773; called by muse, mutect2, varscan2
- TET2 | c.2368C>T p.Q790* | Nonsense Mutation (SNP) | VAF 47/161 reads (29%) | catalogued as rs746098745, COSV54407487; called by muse, mutect2, varscan2
- TFAP2D | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99146729; called by muse, mutect2, varscan2
- THADA | c.3493C>T p.P1165S | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866355500; called by muse, mutect2, varscan2
- THBS1 | c.3185C>T p.S1062F | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs949231985; called by muse, mutect2, varscan2
- THSD7B | c.2101C>T p.R701W | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190732494, COSV55726800, COSV55727651; called by muse, mutect2, varscan2
- TLR2 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1433553966; called by muse, mutect2, varscan2
- TLR5 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as rs754518563; called by muse, mutect2, varscan2
- TMEM121B | c.1510C>T p.L504F | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs1273769467, COSV58897577; called by muse, mutect2, varscan2
- TMEM132D | c.2774G>A p.G925E | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101242511; called by muse, mutect2, varscan2
- TMEM17 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1368173821; called by muse, mutect2, varscan2
- TMEM198 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV54716982; called by muse, mutect2, varscan2
- TOGARAM2 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV65422598, COSV65424065; called by muse, mutect2, varscan2
- TP63 | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 37/292 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV53212359; called by muse, mutect2, varscan2
- TPO | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV100220960, COSV61111356; called by muse, mutect2, varscan2
- TRDN | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.177); catalogued as COSV100521951; called by muse, mutect2, varscan2
- TRPA1 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200400167; called by muse, mutect2, varscan2
- TRPC7 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs776675990, COSV61464386; called by muse, mutect2, varscan2
- TYW1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs767521392; called by muse, mutect2, varscan2
- UBTFL1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.642); catalogued as rs759146588, COSV73297914; called by muse, mutect2, varscan2
- UFL1 | c.2161C>T p.P721S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.079); catalogued as COSV65150025; called by muse, mutect2, varscan2
- UGT2B17 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as rs756634898, COSV58502163; called by muse, mutect2, varscan2
- UGT3A1 | c.594G>A p.W198* | Nonsense Mutation (SNP) | VAF 39/121 reads (32%) | catalogued as COSV99072892; called by muse, mutect2, varscan2
- UNC5D | c.2807C>T p.S936L | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV54791003, COSV54831029; called by muse, mutect2, varscan2
- UNC79 | c.4243G>A p.D1415N (on ENST00000393151 / NM_001346218.2; = p.D1238N on NM_020818.5) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs148868238; called by muse, mutect2, varscan2
- USH1C | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50015844; called by muse, mutect2, varscan2
- USP2 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs375539156; called by muse, mutect2, varscan2
- VASP | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs139737818, COSV55606558; called by muse, mutect2, varscan2
- VCL | c.585G>A p.M195I | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.851); catalogued as rs759141517; called by muse, mutect2, varscan2
- VNN1 | c.1430G>A p.G477E | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764175513; called by muse, mutect2, varscan2
- WASHC1 | c.1312T>A p.F438I | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs778303838; called by muse, varscan2
- WDR44 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.027); catalogued as rs763160154; called by muse, mutect2, varscan2
- WDR64 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV63792682; called by muse, mutect2, varscan2
- WDR87 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as rs1371041062, COSV58192838; called by mutect2, varscan2
- WFDC8 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.591); catalogued as COSV51489681; called by muse, mutect2, varscan2
- WNT5A | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52835987; called by muse, mutect2
- XIRP1 | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs569159181; called by muse, mutect2, varscan2
- XIRP2 | c.739G>A p.E247K (on ENST00000628543; = p.E422K on NM_152381.6) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.395); catalogued as COSV54735969; called by muse, mutect2, varscan2
- XIRP2 | c.2797G>A p.E933K (on ENST00000628543; = p.E1108K on NM_152381.6) | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV54706281; called by muse, mutect2, varscan2
- ZBBX | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100283839, COSV56786622; called by muse, mutect2, varscan2
- ZBED4 | c.3137C>T p.S1046F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as rs1157112651, COSV99079914; called by muse, mutect2, varscan2
- ZBED9 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV71729759; called by muse, mutect2, varscan2
- ZBED9 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1359504265, COSV71729335; called by muse, mutect2, varscan2
- ZBED9 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as rs866308071, COSV71729246; called by muse, mutect2, varscan2
- ZDBF2 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV65625353; called by muse, mutect2, varscan2
- ZFHX3 | c.9694C>T p.R3232C | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); catalogued as rs1273492220, COSV51723812; called by muse, mutect2, varscan2
- ZFHX3 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51721670; called by muse, mutect2, varscan2
- ZFHX4 | c.9616G>A p.E3206K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as COSV99268039; called by muse, mutect2, varscan2
- ZMYM1 | c.2663C>T p.S888F | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV104417141; called by muse, mutect2, varscan2
- ZNF221 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs576730468, COSV52108933; called by muse, mutect2, varscan2
- ZNF226 | c.985C>T p.H329Y | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs868010515; called by muse, mutect2, varscan2
- ZNF248 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV61997715; called by muse, mutect2, varscan2
- ZNF518B | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs746868476, COSV58721660; called by muse, mutect2, varscan2
- ZNF526 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.45); catalogued as rs780497404; called by muse, mutect2, varscan2
- ZNF729 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762673679; called by muse, mutect2, varscan2
- ZNF729 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as rs1209506679; called by muse, mutect2, varscan2
- AASS | c.2540C>T p.P847L | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- ABCA9 | c.4444G>A p.A1482T | Missense Mutation (SNP) | VAF 89/140 reads (64%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- ABCB5 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ABCC12 | c.3783A>T p.E1261D | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACSBG2 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ACSS1 | c.1891G>A p.V631M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- ACSS1 | c.1891-1G>A p.X631_splice | Splice Site (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- ACTC1 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ACTRT2 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADAM12 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ADAMTS19 | c.2021G>A p.R674K | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADGRF2 | c.1186G>A p.G396S (on ENST00000296862 / NM_001368115.2; = p.G328S on NM_153839.7) | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ADGRF2 | c.1187G>A p.G396D (on ENST00000296862 / NM_001368115.2; = p.G328D on NM_153839.7) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRG4 | c.1163C>T p.T388I | Missense Mutation (SNP) | VAF 75/98 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADGRL2 | c.821G>A p.W274* | Nonsense Mutation (SNP) | VAF 80/214 reads (37%) | called by muse, mutect2, varscan2
- ADGRL3 | c.3309T>G p.N1103K (on ENST00000506720 / NM_001322402.2; = p.N1035K on NM_015236.6) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AJAP1 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AK9 | c.5392C>T p.L1798F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AL645922.1 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ALDH18A1 | c.2092G>A p.V698I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ALG10 | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ALK | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 38/212 reads (18%) | called by muse, varscan2
- ANK3 | c.7892C>T p.P2631L | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ANK3 | c.6904C>T p.P2302S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD30A | c.3349G>A p.E1117K (on ENST00000611781; = p.E1061K on NM_052997.2) | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- ANKRD52 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- AOX1 | c.2104C>A p.P702T | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- AP4E1 | c.746C>T p.T249I | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- APBA3 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- APBA3 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APBB2 | c.1720C>T p.P574S (on ENST00000295974 / NM_001166050.2; = p.P575S on NM_004307.2) | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- APEX2 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AR | c.875G>C p.G292A | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ARHGAP11A | c.3011C>T p.S1004F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGAP27 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP30 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGAP35 | c.2282C>T p.S761F | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- ARHGDIA | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF33 | c.1191G>T p.Q397H | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID2 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, varscan2
- ARMC1 | c.387del p.A131Lfs*19 | Frame Shift Del (DEL) | VAF 18/120 reads (15%) | called by mutect2, pindel, varscan2
- ARMCX5-GPRASP2 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASIC5 | c.300T>G p.Y100* | Nonsense Mutation (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2
- ATMIN | c.2441C>T p.S814F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ATP1A4 | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATP1A4 | c.2426G>A p.G809E | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP1B2 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BCAT2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BDP1 | c.4739G>C p.R1580T | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- BPI | c.261G>A p.M87I (on ENST00000262865; = p.M83I on NM_001725.3) | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- BRSK1 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1orf94 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); called by muse, mutect2
- C4orf54 | c.3715G>A p.E1239K | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- C6 | c.2451G>T p.K817N | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C6orf132 | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- C7orf31 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2, varscan2
- CABLES2 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CACNA1I | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- CACNA1S | c.5276C>T p.P1759L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CATSPERE | c.620T>G p.F207C | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CBLIF | c.262A>G p.T88A | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- CBY2 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC110 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- CCDC144A | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | called by muse, varscan2
- CCDC170 | c.1875G>A p.M625I | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, varscan2
- CCDC185 | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- CCDC77 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- CCNB3 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- CD2AP | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- CDC20B | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CDC42EP2 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CDK13 | c.1627C>T p.L543F | Missense Mutation (SNP) | VAF 110/202 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- CEACAM7 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- CEP162 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CEP63 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CFAP74 | c.4387A>T p.K1463* | Nonsense Mutation (SNP) | VAF 31/120 reads (26%) | called by muse, varscan2
- CFAP91 | c.1344+1G>A p.X448_splice | Splice Site (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2
- CFH | c.3677C>T p.P1226L | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFHR1 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 62/320 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CHD9 | c.7394C>T p.S2465F (on ENST00000398510 / NM_001382353.1; = p.S2449F on NM_025134.7) | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- CHRNA9 | c.658T>G p.C220G | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRNB2 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CINP | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CLCA4 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CLIP4 | c.1793C>T p.S598F | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CMYA5 | c.7814C>T p.A2605V | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CNTN4 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- COCH | c.1681A>G p.I561V (on ENST00000216361 / NM_001347720.1; = p.I496V on NM_004086.3) | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- COG7 | c.1234T>A p.F412I | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- COL11A1 | c.2135G>A p.G712D | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL11A1 | c.2134G>A p.G712S | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL14A1 | c.5110C>T p.P1704S | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- COL1A1 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL26A1 | c.910C>T p.P304S (on ENST00000313669 / NM_001278563.3; = p.P302S on NM_133457.4) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A5 | c.5198C>T p.S1733F | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- COL9A1 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- CPAMD8 | c.1264C>T p.P422S (on ENST00000651564; = p.P375S on NM_015692.5) | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CST5 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CUL4B | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- CUX1 | c.3212C>T p.T1071I | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CYP2A6 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- CYP2B6 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CYP2C8 | c.332-8T>C | Splice Region (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- DAPL1 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCAF12L1 | c.985G>C p.V329L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DCTN1 | c.3223G>T p.G1075W | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- DENND2C | c.661T>G p.S221A | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DGKK | c.1913T>C p.V638A | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- DIP2C | c.2351G>A p.G784E | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DMBT1 | c.6267del p.T2090Lfs*86 (on ENST00000338354 / NM_001377530.1; = p.T1333Lfs*86 on NM_004406.3) | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | called by mutect2, pindel, varscan2
- DMD | c.8346G>A p.M2782I | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH5 | c.6033T>A p.D2011E | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH6 | c.8779_8784del p.R2927_Q2928del | In Frame Del (DEL) | VAF 43/176 reads (24%) | called by mutect2, pindel, varscan2
- DNAJC22 | c.670T>C p.F224L | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPYD | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DSP | c.7781C>T p.S2594F | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- DSPP | c.526G>C p.V176L | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DTX3 | c.313T>G p.C105G | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- DUXB | c.214A>T p.K72* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- EDNRA | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EFCAB9 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- EGFL6 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF2AK1 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 39/362 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EIF2S1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EIF3B | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 17/185 reads (9%) | called by muse, mutect2
- ELAC2 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 70/227 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- ENO4 | c.166-1G>A p.X56_splice | Splice Site (SNP) | VAF 16/44 reads (36%) | called by muse, varscan2
- ENPP4 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- EPB41L1 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA4 | c.2713C>T p.P905S | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EPPK1 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPX | c.1664T>A p.L555Q | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ERCC4 | c.1474T>A p.L492M | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ERMN | c.619A>G p.K207E | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ERVFRD-1 | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ESPNL | c.1822A>G p.K608E | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.194); called by muse, mutect2
- FAM120C | c.2867G>A p.G956E | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM122A | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- FAM135B | c.1587T>A p.Y529* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- FAM153A | c.840G>A p.V280= | Splice Region (SNP) | VAF 4/23 reads (17%) | called by mutect2, varscan2
- FAM185A | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM214B | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FAM47A | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT tolerated (0.47); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- FAM47A | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- FARS2 | c.424del p.D142Tfs*5 | Frame Shift Del (DEL) | VAF 32/190 reads (17%) | called by mutect2, pindel, varscan2
- FAT1 | c.3677C>T p.S1226L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FAT2 | c.4168G>A p.D1390N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FAT2 | c.2720C>T p.S907F | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT2 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- FBN3 | c.5317C>T p.P1773S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.927); called by muse, mutect2
- FCGBP | c.7861G>A p.E2621K | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0.035); called by muse, mutect2
- FCN2 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FGA | c.2159G>A p.R720K | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FKBP15 | c.2171C>T p.S724F | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- FLG | c.2039C>T p.S680L | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FLG2 | c.4072G>A p.G1358R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- FLNC | c.2591C>T p.S864F | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FLT4 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FMO1 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FOXP3 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FOXRED2 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FREM2 | c.6505G>A p.G2169R | Missense Mutation (SNP) | VAF 61/87 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FRMPD4 | c.1079G>A p.W360* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- FSCB | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- FSHR | c.154A>T p.R52W | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- FSIP2 | c.5182G>A p.E1728K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- FUT8 | c.1304C>T p.S435L (on ENST00000360689 / NM_001371534.1; = p.S272L on NM_004480.4) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FYB2 | c.1952A>C p.K651T | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GAS2L3 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- GCC2 | c.3331G>A p.E1111K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- GLI2 | c.971T>G p.L324R | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- GLI3 | c.1242G>A p.Q414= | Splice Region (SNP) | VAF 34/164 reads (21%) | called by muse, mutect2, varscan2
- GLI3 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- GPX8 | c.492G>A p.W164* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- GREB1L | c.3031-1G>A p.X1011_splice | Splice Site (SNP) | VAF 16/125 reads (13%) | called by muse, mutect2, varscan2
- GRIK3 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRIK3 | c.39G>A p.W13* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- GRIN3A | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- GRIN3B | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GSTA1 | c.395_402del p.Y132Cfs*3 | Frame Shift Del (DEL) | VAF 27/94 reads (29%) | called by mutect2, pindel, varscan2
- GTF3C2 | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GUCY1A2 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GUCY2C | c.2012A>C p.Q671P | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HAO1 | c.957G>A p.W319* | Nonsense Mutation (SNP) | VAF 61/123 reads (50%) | called by muse, mutect2, varscan2
- HAUS6 | c.2488T>A p.L830I | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HERC1 | c.9703C>T p.L3235F | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HIF1AN | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- HIVEP1 | c.4895C>T p.S1632L | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- HIVEP3 | c.5698C>T p.P1900S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- HMCN1 | c.14783C>T p.S4928F | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPH2 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HNRNPUL1 | c.647-1G>A p.X216_splice | Splice Site (SNP) | VAF 42/142 reads (30%) | called by muse, mutect2, varscan2
- HOOK1 | c.2144G>A p.R715K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXD3 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXD3 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HRNR | c.7370C>T p.S2457F | Missense Mutation (SNP) | VAF 36/704 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.069); called by muse, mutect2
- HSP90AA1 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HYDIN | c.12049G>A p.E4017K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- IFNAR2 | c.237del p.K80Rfs*31 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | called by pindel, varscan2
- IGF2BP2 | c.357_363del p.T120Lfs*14 | Frame Shift Del (DEL) | VAF 13/126 reads (10%) | called by mutect2, pindel
- IGSF3 | c.3461C>T p.S1154F (on ENST00000369486 / NM_001007237.3; = p.S1174F on NM_001542.4) | Missense Mutation (SNP) | VAF 88/275 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- IL18RAP | c.71-1G>A p.X24_splice | Splice Site (SNP) | VAF 8/17 reads (47%) | called by muse, varscan2
- IL18RAP | c.141T>A p.D47E | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.452); called by muse, varscan2
- IL1RAPL2 | c.1484A>T p.N495I | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- IL7R | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ITPR1 | c.2938C>T p.Q980* (on ENST00000354582; = p.Q965* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2
- KCNAB2 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KCNMB2 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- KDM4B | c.1915C>T p.P639S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- KDM4B | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KDM5C | c.3359A>G p.E1120G | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- KIF18A | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIF7 | c.3948G>A p.W1316* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- KIFC1 | c.265A>G p.K89E | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- KLK11 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- KLK4 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- KPNA2 | c.998A>T p.D333V | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- KPNA6 | c.1159C>T p.L387F | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- KRT75 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- KRTAP27-1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KRTAP6-1 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 75/191 reads (39%) | PolyPhen benign (0.086); called by muse, mutect2, varscan2
- LHX8 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 53/180 reads (29%) | called by muse, mutect2, varscan2
- LHX9 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- LMOD1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- LMX1B | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- LPIN1 | c.2168C>T p.S723F | Missense Mutation (SNP) | VAF 21/255 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- LRP1B | c.5350del p.T1784Pfs*14 | Frame Shift Del (DEL) | VAF 20/114 reads (18%) | called by mutect2, pindel, varscan2
- LRP2 | c.5317C>T p.P1773S | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRPPRC | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRTM2 | c.1083G>A p.W361* | Nonsense Mutation (SNP) | VAF 27/145 reads (19%) | called by muse, mutect2, varscan2
- LRRTM2 | c.1082G>A p.W361* | Nonsense Mutation (SNP) | VAF 27/144 reads (19%) | called by muse, mutect2, varscan2
- LTF | c.1168T>G p.C390G | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LYPLA2 | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- MALRD1 | c.5926G>A p.E1976K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MAP1A | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MAP3K9 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- MAP7D2 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAST1 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MDGA2 | c.929C>T p.S310L (on ENST00000399232 / NM_001113498.2; = p.S12L on NM_182830.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- ME3 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- MIIP | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- MOCS3 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- MOS | c.744_751del p.L250Rfs*7 | Frame Shift Del (DEL) | VAF 24/100 reads (24%) | called by mutect2, pindel, varscan2
- MRC2 | c.4082C>T p.P1361L | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.57); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- MRGPRG | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRM2 | c.410A>C p.Q137P | Missense Mutation (SNP) | VAF 38/446 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2
- MSH3 | c.1753C>T p.L585F | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MUC19 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- MUC22 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- MUC22 | c.3836C>T p.S1279F | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.04); called by muse, mutect2, varscan2
- MYH13 | c.5527G>A p.G1843R | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MYH14 | c.5509G>C p.E1837Q | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH2 | c.4888G>A p.E1630K | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- MYH8 | c.4963G>A p.E1655K | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- MYO10 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYO15A | c.5662G>A p.E1888K | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO7B | c.2391G>A p.W797* | Nonsense Mutation (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
- MYOCD | c.1694T>G p.F565C | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NAPEPLD | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NAV2 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NEB | c.12215C>T p.S4072F | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- NEB | c.6121G>A p.D2041N | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLGN4X | c.2080_2094delinsT p.A694* | Frame Shift Del (DEL) | VAF 28/127 reads (22%) | called by pindel, varscan2*
- NOBOX | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT tolerated (0.16); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- NSG2 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NSG2 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NSL1 | c.570C>T p.S190= | Splice Region (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- NTN5 | c.1074G>A p.M358I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.977); called by mutect2, varscan2
- NUTF2 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 36/137 reads (26%) | called by muse, mutect2, varscan2
- NWD2 | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- OR1A1 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by mutect2, varscan2
- OR2AP1 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- OR2M3 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR52I1 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- OR6C1 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- OR6C2 | c.530G>T p.C177F | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- OVCH1 | c.3027G>A p.W1009* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- PABPC1L | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PALM3 | c.1640G>A p.G547E (on ENST00000340790; = p.G562E on NM_001145028.2) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by mutect2, varscan2
- PAQR6 | c.179+7G>A | Splice Region (SNP) | VAF 36/134 reads (27%) | called by muse, mutect2, varscan2
- PBX1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2
- PCDH15 | c.4915G>T p.E1639* | Nonsense Mutation (SNP) | VAF 36/141 reads (26%) | called by muse, mutect2, varscan2
- PCDHA13 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- PCDHA3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- PCDHA9 | c.2287_2291delinsAGTCC p.G763_K764delinsSP | Missense Mutation (ONP) | VAF 4/45 reads (9%) | called by muse*, mutect2*, pindel
- PCDHB6 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- PCSK1N | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- PCSK2 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PDE8B | c.786G>C p.Q262H | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PEBP4 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- PET100 | c.115-8C>T | Splice Region (SNP) | VAF 39/116 reads (34%) | called by muse, mutect2, varscan2
- PEX5L | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PKHD1 | c.6825G>A p.M2275I | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLAU | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLBD1 | c.1480-1G>A p.X494_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2
- PLCB1 | c.2905T>C p.S969P | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PLCB1 | c.2906C>T p.S969F | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PLCB2 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLPPR4 | c.2092C>T p.H698Y | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.242); called by muse, mutect2, varscan2
749 further variants in this file (146 protein-altering or splice-affecting, 422 silent, 181 other) are not listed here.
